Somatic mutation profile of tumor specimen C3N-00249-03 (aliquot CPT0025750009_1) from CPTAC case C3N-00249, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.5 years (26,108 days).
Specimen C3N-00249-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6645ae5-ad06-4fca-82da-bf644ed07c2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00249-31 (Blood Derived Normal), aliquot CPT0028460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72bbaf3e-64c8-43f8-86c0-f8787fa84ff3

The open-access MAF lists 43 somatic variants for this specimen: 23 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 12, 3'UTR 2, RNA 2, 3'Flank 1, Intron 1, 5'Flank 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 67/311 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1088G>A p.C363Y | Missense Mutation (SNP) | VAF 76/253 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876660556, CD064635, COSV61684006, COSV61691764, COSV61695842; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.193A>T p.R65* | Nonsense Mutation (SNP) | VAF 95/380 reads (25%) | catalogued as rs1555526721, COSV52689560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMH | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 103/323 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as rs747303126; called by muse, mutect2, varscan2
- ARHGAP33 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 38/463 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs763084663, COSV99139014; called by muse, mutect2
- LDHD | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283312426; called by muse, mutect2
- MMP24 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 125/639 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as rs1437199431; called by muse, mutect2, varscan2
- NRP2 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 193/814 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs537993529, COSV55933480; called by muse, mutect2, varscan2
- PCDHGA4 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs1157536797, COSV54035049; called by muse, mutect2
- PLEKHG3 | c.1760G>T p.S587I (on ENST00000394691; = p.S643I on NM_001308147.2) | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773411595; called by muse, mutect2, varscan2
- UNC45B | c.2056G>A p.G686S | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs1239341475; called by muse, mutect2, varscan2
- ADAMTS2 | c.3178A>G p.K1060E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AGBL1 | c.2644G>A p.G882S | Missense Mutation (SNP) | VAF 135/434 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FLRT2 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); called by muse, varscan2
- GOLGA8F | c.364G>A p.E122K (on ENST00000526619; = p.E328K on NM_001350920.2) | Missense Mutation (SNP) | VAF 113/1312 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- LRRC7 | c.4547G>T p.G1516V (on ENST00000651989 / NM_001370785.2; = p.G1436V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEL2 | c.2867G>T p.S956I | Missense Mutation (SNP) | VAF 87/339 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NLRP6 | c.620G>C p.G207A | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDIA4 | c.1135G>A p.G379S (on ENST00000286091 / NM_001371244.1; = p.G378S on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/333 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SLC22A14 | c.1042A>C p.I348L | Missense Mutation (SNP) | VAF 103/481 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- SLC25A10 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- STAU2 | c.521A>C p.K174T (on ENST00000524300 / NM_001164380.2; = p.K142T on NM_014393.2) | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TOGARAM1 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 89/662 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CATSPERG | c.3153C>T p.T1051= | Silent (SNP) | VAF 71/518 reads (14%) | catalogued as rs1488068677; called by muse, mutect2, varscan2
- CCT6A | c.849C>T p.G283= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as rs754612296, COSV51906522; called by muse, mutect2, varscan2
- GTF2H3 | c.630G>A p.T210= | Silent (SNP) | VAF 154/749 reads (21%) | called by muse, mutect2, varscan2
- IGHD5-12 | c.12G>T p.V4= | Silent (SNP) | VAF 34/342 reads (10%) | called by muse, varscan2
- KANSL1 | c.3108G>A p.R1036= (on ENST00000574590 / NM_001193465.2; = p.R1037= on NM_015443.4) | Silent (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- LPA | c.117G>A p.T39= | Silent (SNP) | VAF 199/923 reads (22%) | catalogued as rs372624567; called by muse, mutect2, varscan2
- PCDHGA9 | c.237G>C p.P79= | Silent (SNP) | VAF 81/383 reads (21%) | catalogued as COSV99529111; called by muse, mutect2, varscan2
- PCOLCE | c.852C>T p.P284= | Silent (SNP) | VAF 97/251 reads (39%) | catalogued as rs757331910; called by muse, mutect2, varscan2
- PIGQ | c.1030C>T p.L344= | Silent (SNP) | VAF 62/384 reads (16%) | called by muse, mutect2, varscan2
- RRP8 | c.993T>C p.H331= | Silent (SNP) | VAF 75/437 reads (17%) | called by muse, mutect2, varscan2
- SCAMP4 | c.321G>A p.A107= | Silent (SNP) | VAF 60/319 reads (19%) | catalogued as rs370734476; called by muse, mutect2, varscan2
- WRAP73 | c.690C>T p.A230= | Silent (SNP) | VAF 82/454 reads (18%) | called by muse, mutect2, varscan2
- FCAR | c.-2C>T | 5'UTR (SNP) | VAF 54/321 reads (17%) | catalogued as rs773500089, COSV100628994; called by muse, mutect2, varscan2
- OSTCP1 | n.321C>T | RNA (SNP) | VAF 119/538 reads (22%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157498 C>T | 3'Flank (SNP) | VAF 290/1420 reads (20%) | catalogued as rs782165717; called by muse, mutect2, varscan2
- PPP6R3 | c.*1750T>A | 3'UTR (SNP) | VAF 20/532 reads (4%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34158640 A>T | 5'Flank (SNP) | VAF 49/207 reads (24%) | called by muse, mutect2, varscan2
- SLC6A3 | c.*13C>T | 3'UTR (SNP) | VAF 155/721 reads (21%) | catalogued as rs748857322, COSV54363969; called by muse, mutect2, varscan2
- SPATA31D5P | n.1149C>A | RNA (SNP) | VAF 51/275 reads (19%) | called by muse, mutect2, varscan2
- TBL2 | c.130+1778C>G | Intron (SNP) | VAF 73/272 reads (27%) | called by muse, mutect2, varscan2
